Somatic mutation profile of tumor specimen 0DWVFG from CCDI case PBCPEI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 16.4 years (5,987 days).
Specimen 0DWVFG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce7de3ba-0e66-4303-9b21-57a983238f07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWVEG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14888f62-9982-4ab5-8a0a-da4fd7861827

The open-access MAF lists 27 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Intron 3, Nonsense Mutation 3, 3'Flank 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 186/861 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CACNA1F | c.4098C>G p.F1366L | Missense Mutation (SNP) | VAF 20/739 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59907213; called by muse, mutect2
- CBFA2T3 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs144418331; called by muse, mutect2, varscan2
- GOLGA6L9 | c.336C>G p.I112M | Missense Mutation (SNP) | VAF 28/1009 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as rs1360383468; called by muse, mutect2
- RFWD3 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 24/908 reads (3%) | catalogued as COSV63097798; called by muse, mutect2
- C1QTNF9 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 32/758 reads (4%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.493); called by muse, mutect2
- FGD6 | c.3491C>G p.S1164* | Nonsense Mutation (SNP) | VAF 28/596 reads (5%) | called by muse, mutect2
- HYI | c.150_160del p.A51Sfs*88 (on ENST00000372434 / NM_001330526.2; = p.A51Sfs*63 on NM_031207.6) | Frame Shift Del (DEL) | VAF 80/350 reads (23%) | called by mutect2, varscan2
- KDELR3 | c.435G>C p.E145D | Missense Mutation (SNP) | VAF 30/842 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.405); called by muse, mutect2
- LRGUK | c.1940T>C p.L647P | Missense Mutation (SNP) | VAF 23/826 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- NOTUM | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 20/551 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- PIK3C2B | c.4018C>T p.Q1340* | Nonsense Mutation (SNP) | VAF 24/923 reads (3%) | called by muse, mutect2
- PLEKHA8 | c.89A>T p.Y30F | Missense Mutation (SNP) | VAF 42/736 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RAD21L1 | c.1002G>C p.L334F | Missense Mutation (SNP) | VAF 40/974 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- TRMT112 | c.280A>G p.I94V | Missense Mutation (SNP) | VAF 14/393 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TTN | c.45432-1G>C p.X15144_splice (on ENST00000591111; = p.X7720_splice on NM_003319.4) | Splice Site (SNP) | VAF 19/652 reads (3%) | called by muse, mutect2
- ZNF669 | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 32/968 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.221); called by muse, mutect2
- CCDC146 | c.1429C>T p.L477= | Silent (SNP) | VAF 18/644 reads (3%) | called by muse, mutect2
- GRK7 | c.21G>A p.L7= | Silent (SNP) | VAF 12/312 reads (4%) | called by muse, mutect2
- ILDR2 | c.1815C>T p.Y605= | Silent (SNP) | VAF 34/505 reads (7%) | catalogued as COSV99614582; called by muse, mutect2
- NAA30 | c.285C>T p.L95= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as rs1282397013; called by muse, mutect2
- NME4 | c.21C>T p.R7= | Silent (SNP) | VAF 83/272 reads (31%) | called by muse, mutect2, varscan2
- USP32 | c.492A>G p.L164= | Silent (SNP) | VAF 196/791 reads (25%) | catalogued as rs760959071; called by muse, mutect2, varscan2
- AC114498.2 | chr1:629988 G>A | 3'Flank (SNP) | VAF 431/668 reads (65%) | called by muse, mutect2, varscan2
- CD53 | c.505-34G>A | Intron (SNP) | VAF 99/394 reads (25%) | called by muse, mutect2, varscan2
- DDX39A | c.732+55G>A | Intron (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- PLEKHA1 | c.682-70G>C | Intron (SNP) | VAF 37/131 reads (28%) | called by muse, mutect2, varscan2
